Somatic mutation profile of tumor specimen TARGET-10-PARMMA-09A (aliquot TARGET-10-PARMMA-09A-01D) from TARGET case TARGET-10-PARMMA, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,866 days).
Specimen TARGET-10-PARMMA-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c2e3c261-4391-4d76-8fcd-3c282d9a13e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARMMA-10A (Blood Derived Normal), aliquot TARGET-10-PARMMA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbc69d5e-5701-4ceb-94b4-d02aeaeac6d8

The open-access MAF lists 17 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 4, RNA 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC178 | c.541C>T p.R181W | Missense Mutation (SNP) | VAF 98/222 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141279050; called by muse, mutect2, varscan2
- CDHR1 | c.2141C>T p.A714V | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.006); catalogued as COSV100259462; called by muse, mutect2, varscan2
- DHCR7 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as rs80338855, CM001124; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- GIN1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV101204414; called by muse, mutect2, varscan2
- BRWD3 | c.1079C>T p.S360L | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- DAB1 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- H2AC13 | c.323T>C p.V108A | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- HRNR | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- IGKV2D-24 | chr2:90005618 ACACAATTTCCTCACACAGTGGTA>CTACAAACCC | Missense Mutation (DEL) | VAF 4/25 reads (16%) | called by pindel, varscan2*
- KCNS2 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2
- AFDN | c.117C>T p.F39= | Silent (SNP) | VAF 97/218 reads (44%) | called by muse, mutect2, varscan2
- IGHV3-64 | c.33T>C p.L11= | Silent (SNP) | VAF 111/144 reads (77%) | called by muse, mutect2, varscan2
- MYRF | c.1173C>T p.D391= (on ENST00000278836 / NM_001127392.3; = p.D382= on NM_013279.4) | Silent (SNP) | VAF 53/118 reads (45%) | catalogued as rs773348961; called by muse, mutect2, varscan2
- PHACTR3 | c.1101C>T p.I367= | Silent (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- AC006971.1 | n.4307C>A | RNA (SNP) | VAF 56/119 reads (47%) | called by muse, mutect2, varscan2
- FUT7 | chr9:137034887 G>A | 5'Flank (SNP) | VAF 73/143 reads (51%) | called by muse, mutect2, varscan2
- KRAS | c.*15_*17del | 3'UTR (DEL) | VAF 32/80 reads (40%) | called by pindel, varscan2
